Gene-level copy-number profile of tumor specimen TCGA-CG-4436-01A from TCGA case TCGA-CG-4436, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 57.3 years (20,941 days).
Specimen TCGA-CG-4436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9fb7e867-76a6-4579-9378-df45e1cb0fac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4436-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c76cfd86-c9db-4fec-9a08-f82036872127

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 157; copy number 1: 6,920; copy number 2: 29,222; copy number 3: 16,474; copy number 4: 4,447; copy number 5: 1,594; copy number 6: 928; copy number 8: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4436-01A-01D-1155-01): tumor purity 0.64, ploidy 2.15, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 157 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:171,812,254–184,938,440, 157 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,596 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:25,087,450–45,895,970, 307 genes, copy number 5 (broad region; genes not listed).
- chr7:75,533,298–141,655,244, 1,131 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:33,973,701–34,346,731, 5 genes, copy number 8 (within-gene range 1–8): AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3.
- chr8:36,121,398–38,601,200, 69 genes, copy number 8 (broad region; genes not listed).
- chr13:18,467,172–74,565,445, 882 genes, copy number 5–6 (broad region; genes not listed).
- chr13:100,603,625–114,337,626, 202 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,920. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
